Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ACFR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ACFR-TTP1-A (Primary Tumor).

[page 1 of 11]
Patient:
Pt #:
DOB/Age/Sex:
Patient Phone:
Patient Address:

Submitting MD :
Additional MD's:

Accession #:
Patient Type:
Location:
Admit Date:

Collected:
Received:

-1
-1

SURGICAL PATHOLOGY REPORT

* Added *

SPECIMEN

- 1: Biopsy cardia mass
- 2: Random stomach biopsies - r/o H Pylori
- 3: Sigmoid colon polyp

CLINICAL HISTORY/OPERATIVE FINDINGS

Diarrhea, anemia, gastric mass, sigmoid polyp

SURGICAL PROCEDURE

EGD with biopsy, colonoscopy with polypectomy

GROSS DESCRIPTION

The specimen is received in three parts.

- 1) Received in formalin labeled biopsy cardia mass and consists of multiple irregular fragments of yellow-tan to gray-tan soft tissue ranging from 0.2 up to 0.5 cm in greatest dimension. Submitted entirely in one cassette. An immunohistochemical stain for H. pylori is ordered.
- 2) Received in formalin labeled random stomach biopsy rule out H. pylori and consists of three irregular fragments of gray-tan to yellow-tan soft shaggy tissue ranging from 0.3 up to 0.5 cm in greatest dimension. Submitted entirely in one cassette. An immunohistochemical stain for H. pylori is ordered.
- 3) Received in formalin labeled sigmoid colon polyp and consists of a gray-tan to red-tan fragment of polypoid soft tissue measuring 1.4 x 0.6 x 0.4 cm. The margin of resection is inked black. The specimen is bisected and submitted entirely in one cassette.

MICROSCOPIC EXAMINATION

- 1) A malignant epithelial neoplasm is present. This frequently necrotic tumor produces what might be occasional abortive tubules, but far more commonly grows as flat sheets without distinguishing architectural characteristics. Mitoses are numerous, atypia is notable, and occasional cytoplasmic vacuole formation impart a "signet ring" appearance to some cells. An IHC for Helicobacter is negative.

Fungal hyphae and fragments of squamous mucosa are also seen, suggesting but not confirming that the origin of this lesion might be in the esophagus, but no intestinalized mucosa is identified. Solely on the basis of histological inspection, it is not possible to determine whether this lesion arises in gastric cardia or esophagus.

INTERNAL REVIEW: Malignancy confirmation and identification procedures have been performed by colleague

- 2) The biopsy consists of multiple fragments of gastric fundus, without notable abnormality. An IHC stain for Helicobacter microorganisms is negative.

- 3) Adenomatous colonic mucosa is present, with glands that are enlarged and crowded, nuclei that are prominent, and a generalized loss of cytoplasmic mucin production. There is no high grade dysplasia.

[page 2 of 11]
Pt #: [REDACTED]

FINAL DIAGNOSIS

- 1) GASTRIC CARDIA BIOPSY:
- POORLY DIFFERENTIATED ADENOCARCINOMA WITH SIGNET RING FEATURES
- 2) GASTRIC BIOPSIES:
- FUNDIC MUCOSA WITHOUT SIGNIFICANT HISTOLOGICAL ABNORMALITY
- NO EVIDENCE OF HELICOBACTER MICROORGANISMS
- 3) COLON, SIGMOID:
- TUBULAR ADENOMA
- [REDACTED]
- [REDACTED]

ADDENDUM

Addendum Diagnosis

- 1) GASTRIC CARDIA BIOPSY:
- POORLY DIFFERENTIATED ADENOCARCINOMA WITH SIGNET RING FEATURES
- THE TUMOR IS HER2/NEU POSITIVE (2+)
- [REDACTED]

Addendum Comment

1) Pursuant to established hospital protocol, this neoplasm has been studied for the presence of Her2/Neu using the appropriate immunostain. Inspection reveals that approximately one-third of the tumor cells have reactive membrane, and in over 10% of the tumor cells, the staining pattern is complete.

[REDACTED]

ADDENDUM

Addendum Diagnosis

- 1) GASTRIC ADENOCARCINOMA IS HER-2-neu NEGATIVE BY FISH TECHNIQUE
- [REDACTED]

Addendum Comment

A request has recently been received to perform a HER2/neu by FISH technique on specimen #1, the tumor biopsy of the gastric cardia.

[page 3 of 11]
Pt #: [REDACTED]

The requested study was previously performed in [REDACTED] ^{~+7} but apparently not recorded as an addendum to this case. Those results indicate that the invasive tumor nuclei have no evidence of HER2 gene amplification per ASCO/CAP guidelines. (The observed HER2:D17Z1 ratio is 0.68, with less than 1.8 indicative of amplification absence.)

[page 4 of 11]
Diagnosis: Adenocarcinoma of stomach
Reason for Exam: None Specified

+1725

PROCEDURE: CT Chest / Abd / Pelvis W Contrast

CLINICAL HISTORY: follow-up gastric cancer. Patient is currently undergoing chemotherapy. Adenocarcinoma of stomach.

COMPARISON +1555

TECHNIQUE: Multiple computed tomograms of the chest, abdomen, and pelvis were obtained following intravenous contrast administration. Oral contrast was also administered.

FINDINGS:

CHEST: The visualized portion of the thyroid gland is unremarkable. There are mild vascular calcifications including coronary artery calcifications. There is a port within the right anterior chest.

There are no pleural or pericardial effusions. There is no adenopathy. There is a 4 mm subpleural right lower lobe nodule on series 4 image 77 which is unchanged compared to . The lung parenchyma is otherwise unremarkable.

Abdomen and Pelvis: The liver and spleen are normal in size. There is a 2.3 x 1.6 cm stable low-density lesion within the dome of the right lobe of the liver. There is a stable poorly defined area of hypervascular enhancement within the dome of the liver on series 102 image 87. There is a stable poorly defined low-density lesion within the liver on series 102 image 91. No new focal abnormalities are demonstrated within the liver or spleen.

The gallbladder, pancreas, and right adrenal gland are unremarkable. There are stable left adrenal nodules.

There is no adenopathy. There is no ascites.

There is symmetric renal function. There is no hydronephrosis.

The bladder is unremarkable. There are no abnormal masses within the pelvis. The bowel loops are within normal limits.

IMPRESSION:

Chest:

Benign right lower lobe nodule. Otherwise unremarkable CT scan of the chest. There is no evidence of metastatic disease.

Abdomen/Pelvis:

Stable hepatic lesions probably benign. Stable left adrenal nodules. There is no evidence of metastatic disease.

[page 5 of 11]
MRN:

Name:

DOB:

Sex:

Patient Phone:

Pt ACT#:

[page 6 of 11]
Diagnosis:None Specified
Reason for Exam:None Specified

PROCEDURE:NM PET CT Skull - Thigh Subs

ADM DIAGNOSIS: ESOPHAGEAL CA

ORD # +468

PROCEDURE: PET/CT SKULL-THIGH SUBS ACC#

REPORT: CLINICAL HISTORY: ESOPHAGEAL CA.

RADIOPHARMACEUTICAL: F-18 FDG 12.8 MCI IV.

BLOOD GLUCOSE: 124 MG/DL.

TECHNIQUE: WHOLE-BODY PET CT IMAGING WAS PERFORMED FROM THE MID SKULL TO THE MID THIGH. CT DATA ACQUISITION WAS PERFORMED FOR ANATOMIC LOCALIZATION AND ATTENUATION CORRECTION.

DISCUSSION: COMPARISON IS MADE TO PRIOR PET CT DATE +367

THE ABNORMAL ELEVATED METABOLIC ACTIVITY WITHIN THE LEFT RIB CAGE RELATED TO LEFT SEVENTH RIB FRACTURE HAS RESOLVED. THERE IS NO EVIDENCE OF HYPERMETABOLIC METASTATIC DISEASE NOTED WITHIN THE NECK OR CHEST. NODULAR APPEARANCE OF THE LEFT ADRENAL GLAND IS UNCHANGED. LOW LEVEL METABOLIC ACTIVITY IS ASSOCIATED WITH THIS. THIS HAS A MAXIMAL SUV OF 3.8, UNCHANGED FROM PRIOR STUDY. THERE IS NO EVIDENCE OF HYPERMETABOLIC RETROPERITONEAL OR MESENTERIC LYMPHADENOPATHY. THERE IS PHYSIOLOGIC DISTRIBUTION OF THE RADIOTRACER WITHIN THE PELVIS.

IMPRESSION: NO DEFINITIVE HYPERMETABOLIC METASTATIC DISEASE IS NOTED. PERSISTENT NODULAR APPEARANCE OF THE LEFT ADRENAL GLAND IS NOTED, UNCHANGED. THERE IS LOW LEVEL METABOLIC ACTIVITY ASSOCIATED WITH THIS WHICH CAN BE WITHIN NORMAL LIMITS. CONTINUED SURVEILLANCE RECOMMENDED.

END OF REPORT

[page 7 of 11]
MRN:
Name:
DOB:
Sex:
Patient Phone:

PLACT#:

[page 8 of 11]
Diagnosis:None Specified
Reason for Exam:None Specified

PROCEDURE:CT Chest / Abd / Pelvis W Contrast

- ([REDACTED])
ADM DIAGNOSIS: STOMACH CANCER

ORD #: [REDACTED] +211

PROCEDURE: CT CHEST/AB/PELV W CON Acc# [REDACTED]

REPORT: Clinical History: Followup stomach cancer

Comparison: Prior PET CT examination of [REDACTED] +24
[REDACTED] and CT examination of

+3

Findings:

Axial images of the chest, abdomen and pelvis were obtained after intravenous contrast enhancement.

Chest:

There are questionable filling defects in the bilateral pulmonary arteries, best seen on image [REDACTED] series 3.

The thoracic aorta is normal in caliber with no evidence of dissection or aneurysm. The heart size is normal. There is no pericardial effusion.

The lungs are well-inflated with no consolidation, nodules or masses.

There are no pathologically enlarged lymph nodes in the chest. There is no pleural effusion. No pneumothorax is seen.

Abdomen:

Again noted is a 1.8 cm cyst in the high right hepatic lobe near the dome. Remainder of the liver is normal. The spleen is normal.

Previously noted several nodular densities within and adjacent to the left adrenal gland are stable in size and density, probably representing adenomas. The right adrenal gland is normal.

Previously identified 3.2 cm masslike density in the gastrohepatic ligament is no longer present. This probably representing resolved gastric diverticulum or lymph node. There continue to be a enlarged lymph node in the mesentery at the level of the SMV measuring up to 2.2 cm. A nodular density adjacent to the left kidney is also stable.

The kidneys pancreas, gallbladder, are unremarkable. The abdominal aorta is normal. There is no ascites. There is no small bowel or colonic distention.

[page 9 of 11]
Pelvis:

The urinary bladder, prostate gland and seminal vesicles are unremarkable.

Examination of the bone window reveals no discrete osteolytic or osteoblastic lesion.

IMPRESSION:

Chest:

1. Possible filling defects in the bilateral pulmonary arteries, pulmonary embolism is suspected. Dedicated CTA using PE protocol would be helpful for further characterization.

Abdomen:

1. Previously identified masslike density in the gastrohepatic ligament is no longer present.
2. Mesenteric and retroperitoneal lymphadenopathy is stable.
3. Left adrenal adenomas are stable.

Pelvis:

1. No significant findings.

-----END OF REPORT-----

MRN:

Name:

DOB:

Age:

Sex:

Patient Phone:

Pt ACT#:

[page 10 of 11]
Diagnosis:None Specified
Reason for Exam:None Specified

PROCEDURE:NM PET CT Skull - Thigh Initial

- ORD: [REDACTED]
ADM DIAGNOSIS: MMALIGNANT NEOPLASM GE JUNCTIO

ORD #: [REDACTED] +24

PROCEDURE: PET/CT SKULL-THIGH INITIAL ACC# [REDACTED]

REPORT: CLINICAL HISTORY: ESOPHAGOGASTRIC JUNCTION CANCER

F-18-FDG IMAGING USING 12.99 MCI WAS PERFORMED FROM THE SKULL BASE TO THE MID-THIGH. THE BLOOD GLUCOSE LEVEL WAS 112 MG/DL. A LOW DOSE, UNENHANCED CT SCAN WAS OBTAINED FOR ATTENUATION CORRECTION AND ANATOMIC LOCALIZATION. COMPARISON IS MADE TO A CT SCAN FROM [REDACTED]

+3

THERE IS NO HYPERMETABOLIC ABNORMALITY IN THE NECK.

THERE ARE MULTIPLE HYPERMETABOLIC LYMPH NODES IN THE RIGHT SUPRACLAVICULAR REGION. THESE EXTEND INTO THE MEDIASTINUM TO THE RIGHT OF THE TRACHEA. THERE IS A HYPERMETABOLIC ANTERIOR MEDIASTINAL MASS. THE MAXIMUM SUV IS 8.3. IN THE INFERIOR CHEST, THERE IS A MASS IN THE RIGHT AZYGESOPHAGEAL RECESS. THE MASS MEASURES 21 X 20 X 52 MM. THE MAXIMUM SUV IS 14.4. THERE IS NO HYPERMETABOLIC ABNORMALITY IN THE LUNGS OR HILA.

THERE IS A HYPERMETABOLIC MASS AT THE ESOPHAGOGASTRIC JUNCTION. THE MAXIMUM SUV IS 11.5. THIS MASS EXTENDS ALONG THE LESSER CURVATURE OF THE STOMACH TO THE MASS IN THE GASTROHEPATIC LIGAMENT. THERE ARE MULTIPLE RETROPERITONEAL HYPERMETABOLIC LYMPH NODES. THESE EXTEND INFERIOR TO A LEVEL AT THE LOWER POLE OF THE KIDNEYS. THERE IS A LYMPH NODE IN CT SECTION 102 THAT HAS A MAXIMUM SUV OF 13.4. EVALUATION OF THE LIVER IS LIMITED BY THE PATIENT'S BODY HABITUS AND INCREASED NOISE. SMALL LIVER METASTASES CANNOT BE RULED OUT. NOISE IN THE IMAGES ALSO MAKES DIFFICULT EVALUATION OF BILATERAL ILIAC ADENOPATHY. IT IS SUSPECTED THAT THERE IS INVOLVEMENT OF BILATERAL COMMON ILIAC LYMPH NODES. THE LEFT ADRENAL GLAND NODULES ARE NOT HYPERMETABOLIC.

ACTIVITY WITHIN THE SPINE IS HETEROGENEOUS AND THERE MAY BE SMALL HYPERMETABOLIC METASTASES INVOLVING MULTIPLE VERTEBRAE.

NO ADDITIONAL SIGNIFICANT ABNORMALITY IS SEEN IN THE LOW DOSE CT SCAN.

IMPRESSION:

1. IMAGES ARE LIMITED BY THE PATIENT'S BODY HABITUS AND INCREASED NOISE IN THE IMAGES.
2. HYPERMETABOLIC MASS AT THE ESOPHAGOGASTRIC JUNCTION CONSISTENT WITH A MALIGNANCY. THE MASS AT THE ESOPHAGOGASTRIC JUNCTION APPEARS CONTIGUOUS WITH A MASS IN THE GASTROHEPATIC LIGAMENT.
3. THERE ARE METASTASES TO RIGHT SUPRACLAVICULAR LYMPH NODES, THE

[page 11 of 11]
MEDIASTINUM, RETROPERITONEAL LYMPH NODES, AND POSSIBLY BILATERAL ILIAC LYMPH NODES.

4. POSSIBLE MULTIPLE SPINE METASTASES.

----- END OF REPORT -----

MRN:

Name:

DOB:

Sex:

Patient Phone:

Pt ACT#:

Source: NCI Genomic Data Commons file 347f758b-3bd3-4a92-9362-098000b9477e (ER0274 ER-ACFR Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).